Somatic mutation profile of tumor specimen TCGA-G5-6572-01A (aliquot TCGA-G5-6572-01A-11D-1826-10) from TCGA case TCGA-G5-6572, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 56.1 years (20,475 days).
Specimen TCGA-G5-6572-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7aeb70b2-a797-4971-b258-694627dabd20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G5-6572-10A (Blood Derived Normal), aliquot TCGA-G5-6572-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f58bd52a-b112-43fd-88ee-62ba27606266

The open-access MAF lists 78 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 14, Frame Shift Ins 4, Nonsense Mutation 4, Splice Region 2, Frame Shift Del 2, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.536A>G p.N179S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs398123425, CM002230, CS971621, COSV64869634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 104/133 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1456_1457del p.L486Ifs*6 | Frame Shift Del (DEL) | VAF 60/150 reads (40%) | catalogued as rs587778832; ClinVar: pathogenic; called by pindel, varscan2
- AASS | c.804T>G p.H268Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.873); catalogued as COSV62790010; called by muse, mutect2, varscan2
- ABCA13 | c.8286G>A p.M2762I | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs1169566311, COSV71287749; called by muse, mutect2, varscan2
- AGBL5 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV59936534; called by muse, mutect2, varscan2
- AMIGO3 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1264702216, COSV57538557; called by muse, mutect2, varscan2
- APC | c.3493A>T p.K1165* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV57326930, COSV57341138; called by muse, mutect2, varscan2
- ASTN1 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56069258; called by muse, mutect2, varscan2
- ATP6V1B2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52353641; called by muse, mutect2, varscan2
- CACNA1F | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782241013, COSV59904429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC141 | c.3871T>G p.Y1291D | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.185); catalogued as COSV55373402; called by muse, mutect2, varscan2
- CDK9 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV64723773; called by muse, mutect2, varscan2
- CEP170 | c.2339C>G p.T780S | Missense Mutation (SNP) | VAF 170/358 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770527711, COSV60509032; called by muse, mutect2, varscan2
- CHD6 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 25/169 reads (15%) | catalogued as COSV58557125; called by muse, mutect2, varscan2
- CYP26B1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.094); catalogued as rs200922951, COSV50011796; called by muse, mutect2, varscan2
- DCTN1 | c.1539C>A p.Y513* | Nonsense Mutation (SNP) | VAF 46/184 reads (25%) | catalogued as COSV100720844; called by muse, varscan2
- DOCK2 | c.2072A>G p.H691R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761316602, COSV56958574; called by muse, mutect2, varscan2
- DOCK4 | c.3391T>A p.F1131I | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV69854585; called by muse, mutect2, varscan2
- ERAP1 | c.1979T>A p.L660* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV57087597; called by muse, mutect2, varscan2
- FANCL | c.372T>G p.D124E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as COSV52074473; called by muse, mutect2, varscan2
- GALNT14 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs146467165; called by muse, mutect2, varscan2
- GLI3 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV101229666; called by muse, mutect2, varscan2
- GPR32 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs190167592, COSV54514534; called by muse, mutect2, varscan2
- GRIN2A | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs267604688, COSV58032774; called by muse, mutect2, varscan2
- HTR6 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.8); PolyPhen benign (0.04); catalogued as COSV57033089; called by muse, mutect2, varscan2
- INTS5 | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV57951528; called by muse, mutect2, varscan2
- JAKMIP1 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746008481, COSV51530389; called by muse, mutect2, varscan2
- KCNC1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.404); catalogued as COSV56397237; called by muse, mutect2, varscan2
- KCNJ6 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.443); catalogued as rs780410267, COSV55712309, COSV55714224; called by muse, mutect2, varscan2
- KDM5B | c.1126G>C p.D376H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV52507667; called by muse, mutect2, varscan2
- KIAA1217 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200578654, COSV64605675; called by muse, mutect2, varscan2
- KIF26B | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293822425, COSV63641072; called by muse, mutect2, varscan2
- KIRREL3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1485698805, COSV73106129; called by muse, mutect2, varscan2
- LAMA5 | c.8530G>A p.V2844I | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs760179827, COSV53360082; called by muse, mutect2, varscan2
- LCE1D | c.215G>C p.C72S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | PolyPhen probably damaging (0.978); catalogued as COSV58270905; called by muse, mutect2, varscan2
- MAP3K20 | c.1359G>A p.Q453= | Splice Region (SNP) | VAF 84/145 reads (58%) | catalogued as COSV64378283; called by muse, mutect2, varscan2
- MTF2 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1275020349, COSV64770505; called by muse, mutect2, varscan2
- MYOF | c.4988G>C p.G1663A | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV63704148; called by muse, mutect2, varscan2
- NLRP14 | c.2418G>C p.L806F | Missense Mutation (SNP) | VAF 128/390 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55067083; called by muse, mutect2, varscan2
- OXA1L | c.406-1G>C p.X136_splice (on ENST00000285848; = p.X76_splice on NM_005015.5) | Splice Site (SNP) | VAF 20/46 reads (43%) | catalogued as COSV53537087, COSV99591203; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHA4 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782039700, COSV63541370; called by muse, mutect2, varscan2
- PCDHB5 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1438588601, COSV50650291, COSV99039329; called by muse, mutect2, varscan2
- PGLYRP2 | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV52993591; called by muse, mutect2, varscan2
- PITPNM2 | c.2206A>G p.R736G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99758046; called by muse, mutect2
- PRSS16 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs752971068, COSV57915479; called by muse, mutect2, varscan2
- PTEN | c.734A>C p.Q245P | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1057518538, CD110177, COSV100909109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRH | c.2578C>T p.R860W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778712446, COSV54743607; called by muse, mutect2, varscan2
- SLC16A10 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 129/382 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.264); catalogued as COSV64354296; called by muse, mutect2, varscan2
- SP6 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs527778154, COSV100647095, COSV60617494; called by muse, mutect2, varscan2
- SYNE1 | c.4165A>G p.T1389A (on ENST00000367255 / NM_182961.4; = p.T1396A on NM_033071.3) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV54980509; called by muse, mutect2, varscan2
- TSBP1 | c.255A>T p.L85= (on ENST00000617061; = p.L86= on NM_006781.5) | Splice Region (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100898703; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV54295743; called by muse, mutect2, varscan2
- ZNF263 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs948263417, COSV54596505; called by muse, mutect2, varscan2
- ZNF366 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV59215531; called by muse, mutect2, varscan2
- ZNF98 | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV63335342, COSV63340837; called by muse, mutect2
- ARFGEF1 | c.1493del p.P498Qfs*22 | Frame Shift Del (DEL) | VAF 35/154 reads (23%) | called by mutect2, pindel, varscan2
- NEFH | c.2450dup p.E818Gfs*74 | Frame Shift Ins (INS) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- NOL8 | c.2921dup p.K975Efs*6 | Frame Shift Ins (INS) | VAF 44/112 reads (39%) | called by mutect2, pindel, varscan2
- TGIF1 | c.69dup p.K24Qfs*13 (on ENST00000330513 / NM_001374396.1; = p.K44Qfs*13 on NM_003244.4) | Frame Shift Ins (INS) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.600dup p.H201Sfs*273 | Frame Shift Ins (INS) | VAF 11/20 reads (55%) | called by mutect2, pindel, varscan2
- CDH8 | c.1806C>T p.D602= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs1268371601, COSV54867141, COSV54895067; called by muse, mutect2, varscan2
- CLIC3 | c.246G>A p.L82= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV65406564; called by muse, mutect2, varscan2
- JCAD | c.3282G>A p.V1094= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs569078936, COSV64759607; called by muse, mutect2, varscan2
- JPH4 | c.1143C>T p.A381= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV62508741; called by muse, mutect2, varscan2
- KDM5B | c.1125G>A p.R375= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV52507681; called by muse, mutect2, varscan2
- LILRA2 | c.24G>T p.L8= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV52188164, COSV52191564; called by muse, mutect2
- MEX3B | c.1140C>T p.F380= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV61663434; called by muse, mutect2, varscan2
- NPFFR2 | c.654G>A p.T218= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs141870844; called by muse, mutect2, varscan2
- PCDHB6 | c.1668G>A p.S556= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1554277862, COSV50697688; called by muse, mutect2, varscan2
- RYR2 | c.4488C>T p.P1496= | Silent (SNP) | VAF 42/83 reads (51%) | catalogued as rs370082063; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- ST3GAL4 | c.807C>A p.A269= (on ENST00000392669 / NM_001254758.1; = p.A265= on NM_006278.3) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV57107229; called by muse, mutect2, varscan2
- SYNJ2BP | c.39G>A p.E13= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV56445645; called by muse, mutect2, varscan2
- TNRC6C | c.2787G>A p.K929= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV56945169; called by muse, mutect2, varscan2
- ZNF536 | c.2367G>A p.T789= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs764448830, COSV62824171; called by muse, mutect2, varscan2
- CTSL3P | n.219C>T | RNA (SNP) | VAF 11/27 reads (41%) | catalogued as rs141099992; called by muse, mutect2, varscan2
- HERC2P3 | n.2035T>A | RNA (SNP) | VAF 17/90 reads (19%) | catalogued as rs1228365343; called by mutect2, varscan2
